Somatic mutation profile of tumor specimen TCGA-QR-A70R-01A (aliquot TCGA-QR-A70R-01A-11D-A35D-08) from TCGA case TCGA-QR-A70R, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 43.6 years (15,917 days).
Specimen TCGA-QR-A70R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0d7ee3c-ce56-4aeb-8f7c-63a80e9409da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70R-10A (Blood Derived Normal), aliquot TCGA-QR-A70R-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d439f94a-b2fb-42b6-bac5-8663f844460a

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAI3 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1276084617; called by muse, mutect2, varscan2
- MGAM | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as COSV101516442; called by muse, mutect2
- NBEAL2 | c.3857A>T p.D1286V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1387839840; called by muse, mutect2, varscan2
- PRKD2 | c.1555G>T p.A519S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0.142); catalogued as rs1473416821; called by muse, mutect2, varscan2
- ODAM | c.59C>G p.P20R | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SUN1 | c.482G>T p.G161V (on ENST00000405266 / NM_001367651.1; = p.G111V on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.21); called by muse, mutect2
- HEPN1 | c.42C>T p.G14= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs368280630, COSV53432572; called by muse, mutect2, varscan2
- ING3 | c.516A>G p.L172= | Silent (SNP) | VAF 53/214 reads (25%) | catalogued as rs1287306907; called by muse, mutect2, varscan2
